MMRF case MMRF_1328 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e8a89081-0ada-4b93-9bf9-399597ea9d76

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.3 years (16,918 days); ISS stage: I; Days to last known disease status: 1,434 days (3.9 years); Days to last follow up: 1,434 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 215 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 216 days; Days to treatment end: 544 days (1.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 376 days (1.0 years); Days to treatment end: 754 days (2.1 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 593 days (1.6 years); Days to treatment end: 593 days (1.6 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 595 days (1.6 years); Days to treatment end: 595 days (1.6 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 684 days (1.9 years); Days to treatment end: 685 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 684 days (1.9 years); Days to treatment end: 699 days (1.9 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 684 days (1.9 years); Days to treatment end: 838 days (2.3 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 691 days (1.9 years); Days to treatment end: 699 days (1.9 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 713 days (2.0 years); Days to treatment end: 728 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 741 days (2.0 years); Days to treatment end: 838 days (2.3 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 768 days (2.1 years); Days to treatment end: 838 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 856 days (2.3 years); Days to treatment end: 859 days (2.4 years).
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 862 days (2.4 years); Days to treatment end: 897 days (2.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 880 days (2.4 years); Days to treatment end: 885 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 881 days (2.4 years); Days to treatment end: 885 days (2.4 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 916 days (2.5 years); Days to treatment end: 974 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Other; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 996 days (2.7 years); Days to treatment end: 1,001 days (2.7 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,038 days (2.8 years); Days to treatment end: 1,252 days (3.4 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,038 days (2.8 years); Days to treatment end: 1,252 days (3.4 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 1,182 days (3.2 years); Days to treatment end: 1,252 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Other; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 1,268 days (3.5 years); Days to treatment end: 1,272 days (3.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 1,268 days (3.5 years); Days to treatment end: 1,271 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 1,293 days (3.5 years); Days to treatment end: 1,296 days (3.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 1,334 days (3.7 years); Days to treatment end: 1,334 days (3.7 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Pomalidomide; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 1,334 days (3.7 years); Days to treatment end: 1,371 days (3.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 1,336 days (3.7 years); Days to treatment end: 1,343 days (3.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 1,357 days (3.7 years); Days to treatment end: 1,371 days (3.8 years).
   Treatment given: Therapeutic agents: Panobinostat; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 1,357 days (3.7 years); Days to treatment end: 1,367 days (3.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Seventh line of therapy; Days to treatment start: 1,385 days (3.8 years); Days to treatment end: 1,389 days (3.8 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Seventh line of therapy; Days to treatment start: 1,406 days (3.8 years); Days to treatment end: 1,449 days (4.0 years).
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: Seventh line of therapy; Days to treatment start: 1,406 days (3.8 years); Days to treatment end: 1,455 days (4.0 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Seventh line of therapy; Days to treatment start: 1,406 days (3.8 years); Days to treatment end: 1,448 days (4.0 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Eighth line of therapy; Days to treatment start: 1,441 days (3.9 years); Days to treatment end: 1,455 days (4.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 1.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 3.54 g/L; Immunoglobulin A 32.9 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 3.18 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.08 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.65 mmol/L; Albumin 39 g/L; Total Protein 9.3 g/dL; Glucose 5.28 mmol/L; C-Reactive Protein 0.242 mg/dL.
- Day 107 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.49 mg/dL; Immunoglobulin G 6.4 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.64 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.66 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 7.5 g/dL; Glucose 5.61 mmol/L.
- Day 173 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 6.44 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 1.28 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 5.37 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 7.26 mmol/L.
- Day 272 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 7.15 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.25 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.99 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.
- Day 356 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 1.48 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.99 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 5.56 mmol/L.
- Day 440 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 1.44 µg/mL; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 10.2 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 7.7 g/dL; Glucose 5.23 mmol/L.
- Day 544 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 9.8 g/L; Immunoglobulin A 2.68 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.48 µg/mL; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.72 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 6.22 mmol/L.
- Day 607 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.04 mg/dL; Immunoglobulin G 6.05 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 1.71 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 9.7 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 713 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 5.98 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.28 µg/mL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 13.8 ×10⁹/L; Absolute Neutrophil 11 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.55 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 6.77 mmol/L.
- Day 797 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 4.84 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.97 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 6.22 mmol/L.
- Day 897 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 3.1 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.98 µg/mL; Lactate Dehydrogenase 5.45 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 22 ×10⁹/L; Absolute Neutrophil 15.2 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 6 mmol/L.
- Day 979 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 4.97 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.86 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.99 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 5.34 mmol/L.
- Day 1,038 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 3.69 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.13 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.94 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.16 mmol/L.
- Day 1,154 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 3.33 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 1.83 µg/mL; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.94 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 5.83 mmol/L.
- Day 1,266 (ECOG 1): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 2.42 g/L; Immunoglobulin A 4.6 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 38.3 µg/mL; Lactate Dehydrogenase 4.12 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 0.98 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 5.72 mmol/L.
- Day 1,336 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 2.25 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.76 µg/mL; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.02 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 5.7 g/dL; Glucose 5.83 mmol/L.
- Day 1,434 (ECOG 2): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 1.43 g/L; Immunoglobulin A 4.7 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 3.86 µg/mL; Lactate Dehydrogenase 5.67 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 11 ×10⁹/L; Absolute Neutrophil 8.24 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 1.07 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 8.09 mmol/L.

Other clinical attributes
- Day -7: Weight: 97 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Leukemia; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1328_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_1328_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
